Somatic mutation profile of tumor specimen TARGET-30-PAUBSW-01A (aliquot TARGET-30-PAUBSW-01A-01D) from TARGET case TARGET-30-PAUBSW, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.9 years (1,058 days).
Specimen TARGET-30-PAUBSW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4ee55d5-ff55-44b9-9f9a-5d2ca5855208.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUBSW-10A (Blood Derived Normal), aliquot TARGET-30-PAUBSW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5b917de-bdca-4a97-b734-a2c89594db32

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BARD1 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV53613825; called by muse, mutect2, varscan2
- MED23 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV63430493; called by muse, mutect2, varscan2
- FMN1 | c.*7852T>G | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
